Gene-level copy-number profile of tumor specimen TCGA-AX-A0IW-01A from TCGA case TCGA-AX-A0IW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,488 days).
Specimen TCGA-AX-A0IW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.8c9988b4-30fc-47fc-a0c7-248271506e11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A0IW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4559ecfb-7c5d-40c3-ba29-9a0af707e4dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,432; copy number 2: 30,565; copy number 3: 20,334; copy number 4: 4,566; copy number 5: 1,626; copy number 6: 1,034; copy number 8: 10; copy number 10: 108; copy number 11: 33; copy number 13: 66; copy number 14: 27; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A0IW-01A-11D-A042-01): tumor purity 0.82, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,568,264, 1 gene: LINC00903.
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr6:125,674,353–126,203,817, 8 genes (within-gene range 0–2): LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,906 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,149,183–165,911,618, 678 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:166,474,745–167,058,542, 15 genes, copy number 5: FMO7P, LINC01675, FMO8P, FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1.
- chr2:38,814–55,112,621, 890 genes, copy number 5–6 (broad region; genes not listed).
- chr2:55,547,292–58,159,920, 24 genes, copy number 5 (within-gene range 4–5): PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC132153.1, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1.
- chr2:67,086,446–68,110,948, 10 genes, copy number 6 (within-gene range 4–6): LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D.
- chr3:163,026,396–175,810,548, 148 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:175,718,231–185,633,551, 202 genes, copy number 5 (broad region; genes not listed).
- chr3:185,712,528–185,729,787, 1 gene, copy number 5 (within-gene range 4–5): IGF2BP2-AS1.
- chr3:186,579,476–186,772,986, 1 gene, copy number 6 (within-gene range 4–6): AC068631.1.
- chr3:186,629,936–198,222,513, 268 genes, copy number 5–8 (broad region; genes not listed).
- chr6:167,607–3,115,187, 63 genes, copy number 5 (broad region; genes not listed).
- chr6:49,430,360–69,389,506, 209 genes, copy number 5–14 (within-gene range 2–14) (broad region; genes not listed).
- chr6:104,487,095–108,188,805, 66 genes, copy number 13 (within-gene range 2–13) (broad region; genes not listed).
- chr8:34,174,886–43,674,591, 199 genes, copy number 5–20 (broad region; genes not listed).
- chr20:87,250–3,410,036, 113 genes, copy number 5–6 (broad region; genes not listed).
- chr20:19,000,709–20,370,949, 19 genes, copy number 5: AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1.

Autosomal genes at a single copy (total copy number 1): 1,429. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
